CCDI case PBBVRE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d7717215-f86d-4975-80a2-5c9089fa3579

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,095 days).

Biospecimens (4 samples)
- Sample 0DIFIM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DIFJK, 0DITT4 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJ8KD: Tissue type: Tumor; Specimen type: Solid Tissue.
